Gene-level copy-number profile of tumor specimen TCGA-NC-A5HR-01A from TCGA case TCGA-NC-A5HR, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 75.6 years (27,629 days).
Specimen TCGA-NC-A5HR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.3b5e8e6f-b3b4-443a-9ed7-ceb59514e289.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NC-A5HR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a10d226c-30c4-45d8-9d1c-12e9d999c60b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 23,215; copy number 2: 27,075; copy number 3: 7,378; copy number 4: 257; copy number 5: 241; copy number 6: 1,261; copy number 7: 321; copy number 13: 58.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NC-A5HR-01A-21D-A26L-01): tumor purity 0.66, ploidy 1.8, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes: RNU6-904P, RPS16P3.
- chr2:212,999,691–213,284,205, 5 genes (within-gene range 0–2): IKZF2, AC079610.1, LINC01953, AC079610.2, SPAG16-DT.
- chr5:59,039,761–59,063,503, 1 gene: AC092343.1.
- chr16:78,981,722–79,110,882, 6 genes: AC027279.3, AC027279.2, AC009145.4, AC009145.3, AC009145.1, AC009145.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,881 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:126,704,240–198,222,513, 1,282 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr7:42,794,906–52,503,434, 172 genes, copy number 6 (broad region; genes not listed).
- chr8:37,326,575–38,853,028, 58 genes, copy number 13: AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2.
- chr19:28,602,379–38,899,862, 369 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 20,794. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
